Somatic mutation profile of tumor specimen TCGA-D8-A1JJ-01A (aliquot TCGA-D8-A1JJ-01A-31D-A14K-09) from TCGA case TCGA-D8-A1JJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.7 years (19,966 days).
Specimen TCGA-D8-A1JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd1447d3-789b-4e5d-8662-cce9c9634d17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JJ-10A (Blood Derived Normal), aliquot TCGA-D8-A1JJ-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60290155-ffea-4736-9d6e-da5adc5d9e47

The open-access MAF lists 79 somatic variants for this specimen: 54 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 24, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs762139460, COSV61630540, COSV61632126; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GATA3 | c.878T>G p.M293R | Missense Mutation (SNP) | VAF 35/124 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161496, COSV60515607, COSV60521489; called by muse, mutect2, varscan2
- JUN | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1184098204, COSV64664188, COSV64664376; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 27/73 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 23/41 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4390C>G p.Q1464E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV101000515, COSV65879404; called by muse, mutect2, varscan2
- AFMID | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374429075; called by muse, mutect2, varscan2
- APBB1IP | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV66137193; called by muse, mutect2, varscan2
- ATAD2 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV54888117; called by muse, mutect2, varscan2
- BCAT2 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV60274476; called by muse, mutect2, varscan2
- BTN3A3 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV99764749; called by muse, mutect2
- CCL28 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 85/322 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV63150398; called by muse, mutect2, varscan2
- CCNE2 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV57376368; called by muse, mutect2, varscan2
- CFAP45 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV63649674; called by muse, mutect2
- CNNM1 | c.1396G>T p.V466L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100763757; called by muse, varscan2
- CRYZL1 | c.917A>T p.D306V | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV51680261; called by muse, mutect2, varscan2
- CTPS1 | c.1361G>A p.R454K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV65454679; called by muse, mutect2, varscan2
- DCTN2 | c.259G>A p.E87K (on ENST00000548249 / NM_001261413.2; = p.E92K on NM_006400.4) | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71553500; called by muse, mutect2, varscan2
- DIPK1C | c.1159G>T p.V387F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100679734; called by muse, mutect2
- DLG1 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV58393310; called by muse, mutect2, varscan2
- DOCK11 | c.5804C>T p.S1935F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.637); catalogued as rs1228259022, COSV52249533; called by muse, mutect2, varscan2
- EHBP1 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV50425940, COSV50445805; called by muse, mutect2, varscan2
- FOCAD | c.4689G>C p.M1563I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58105308, COSV58109211; called by muse, mutect2, varscan2
- GLG1 | c.2171A>G p.N724S | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV52676055; called by muse, mutect2, varscan2
- HERC2 | c.1252C>T p.H418Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.069); catalogued as rs1397034313, COSV55354486; called by muse, mutect2, varscan2
- HTATSF1 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54482054; called by muse, mutect2, varscan2
- LRP2 | c.5507A>G p.Y1836C | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55579560; called by muse, mutect2, varscan2
- MACF1 | c.16738G>A p.E5580K (on ENST00000372915; = p.E3622K on NM_012090.5) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV57150183; called by muse, mutect2, varscan2
- NCOR1 | c.7190C>T p.P2397L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1212826063, COSV52000968; called by muse, mutect2, varscan2
- NPBWR1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs146840260, COSV58697900; called by muse, mutect2, varscan2
- OR9G1 | c.653T>A p.L218H | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV100380212; called by muse, mutect2
- PAGE1 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV101093907; called by muse, mutect2
- PCDHB13 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs782053306, COSV53394300; called by muse, mutect2, varscan2
- PHLPP1 | c.4765G>A p.E1589K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.366); catalogued as COSV53041283; called by muse, mutect2, varscan2
- PLCL2 | c.2201G>T p.R734M (on ENST00000615277 / NM_001144382.2; = p.R608M on NM_015184.5) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101196539; called by muse, mutect2
- REC114 | c.792G>C p.L264F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.105); catalogued as COSV58525164; called by muse, mutect2, varscan2
- RPS6KB1 | c.1114C>A p.L372M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV56680182; called by muse, mutect2, varscan2
- SCAF8 | c.1841C>G p.T614R | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as COSV63200383; called by muse, mutect2
- SLC25A14 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.088); catalogued as COSV99502275; called by muse, mutect2, varscan2
- SLC5A3 | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1172262696, COSV62974431; called by muse, mutect2, varscan2
- SLITRK4 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs782728024, COSV62026691; called by muse, mutect2, varscan2
- SMARCAL1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs370663120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMYD2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 64/491 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV65291978; called by muse, mutect2, varscan2
- SNRK | c.1128C>G p.D376E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV56071672; called by muse, mutect2, varscan2
- TMED8 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as COSV53628316; called by muse, mutect2, varscan2
- TRMT9B | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1444672154, COSV67948696; called by muse, mutect2, varscan2
- XRN2 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746894001, COSV65872050; called by muse, mutect2, varscan2
- ZBTB12 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.207); catalogued as rs749307616, COSV64994301; called by mutect2, varscan2
- ZFHX4 | c.7921G>A p.E2641K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1306899927, COSV50510794; called by muse, mutect2, varscan2
- ZFYVE16 | c.2477C>G p.S826C | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV100566160; called by muse, mutect2
- ZNF432 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as COSV99659038; called by muse, mutect2
- ZNF677 | c.776G>C p.R259T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.894); catalogued as COSV61719578, COSV61721993; called by muse, mutect2, varscan2
- IGKV1D-16 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, varscan2
- NBPF11 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- AMER1 | c.2493T>C p.D831= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1261759395, COSV57670981; called by muse, mutect2, varscan2
- ARHGEF7 | c.204C>T p.S68= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1339720813, COSV54553768; called by muse, mutect2, varscan2
- EZR | c.1608C>T p.S536= | Silent (SNP) | VAF 71/257 reads (28%) | catalogued as rs537707819, COSV51916178; called by muse, mutect2, varscan2
- FNDC3A | c.3489G>A p.R1163= (on ENST00000492622 / NM_001079673.2; = p.R1107= on NM_014923.5) | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as COSV68135555; called by muse, mutect2, varscan2
- GPAT2 | c.1939T>C p.L647= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs772422118, COSV64004101; called by muse, mutect2, varscan2
- HBG2 | c.210T>G p.T70= | Silent (SNP) | VAF 41/352 reads (12%) | catalogued as rs768094911, COSV57963509, COSV57963783; called by muse, mutect2, varscan2
- HEPH | c.1605C>T p.L535= (on ENST00000343002; = p.L268= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV57974176; called by muse, mutect2, varscan2
- IGDCC4 | c.2481C>T p.G827= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs1368090341, COSV100732646; called by muse, mutect2, varscan2
- LTN1 | c.3513C>T p.F1171= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV100797862; called by muse, mutect2
- MYO9B | c.4947C>T p.C1649= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV68283502; called by muse, mutect2, varscan2
- NKAPD1 | c.642C>G p.L214= (on ENST00000280352 / NM_001082970.2; = p.L215= on NM_018195.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV54780235; called by muse, mutect2, varscan2
- NTM | c.42C>T p.L14= | Silent (SNP) | VAF 37/374 reads (10%) | catalogued as COSV66186368; called by muse, mutect2
- OR14A16 | c.252G>A p.L84= | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as COSV62926194; called by muse, mutect2
- OSMR | c.1929G>A p.L643= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV57082281; called by muse, mutect2, varscan2
- PCDHA2 | c.1428G>A p.T476= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as COSV65368011; called by muse, mutect2, varscan2
- RLF | c.1047G>A p.T349= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as rs1357892949, COSV65653520; called by muse, mutect2, varscan2
- RSRP1 | c.480G>A p.T160= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV54563514; called by muse, mutect2, varscan2
- SELE | c.885G>A p.E295= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as COSV100324421, COSV60978304; called by muse, mutect2, varscan2
- SRF | c.606G>C p.L202= | Silent (SNP) | VAF 60/161 reads (37%) | catalogued as COSV54840302; called by muse, mutect2, varscan2
- STK32C | c.1278C>T p.L426= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as rs150156301, COSV100063214, COSV53847155; called by muse, mutect2, varscan2
- TSPAN14 | c.24C>T p.N8= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as rs761208641, COSV59370358; called by muse, mutect2, varscan2
- ZBED4 | c.1560G>A p.L520= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs767538197, COSV53468855; called by muse, mutect2, varscan2
- ZFR | c.1425G>A p.S475= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as rs200869684, COSV54049878; called by muse, mutect2, varscan2
- ZNF425 | c.2208G>A p.A736= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs773536439, COSV65203036; called by muse, mutect2, varscan2
- IZUMO4 | c.370+101C>A | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as COSV61433917; called by muse, mutect2, varscan2
